Gene-level copy-number profile of tumor specimen C3L-04033-01 (profiled together with C3L-04033-02) from CPTAC case C3L-04033, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 39.2 years (14,325 days).
Specimen C3L-04033-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 25f5f116-5b9e-442b-8f0a-0fc4de73fe84.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04033-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/d7b52582-13ab-4418-91fb-3ff220cf9ecd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 302; copy number 1: 9; copy number 2: 10,529; copy number 3: 4,732; copy number 4: 30,050; copy number 5: 6,513; copy number 6: 4,009; copy number 7: 1,274; copy number 8: 107; copy number 9: 215; copy number 10: 196; copy number 11: 978.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,389 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:147,930,396–148,516,971, 6 genes, copy number 9 (within-gene range 6–9): ORC4, MBD5, AC019226.1, AC019226.2, AC019070.1, USP12P2.
- chr2:151,247,940–151,380,046, 6 genes, copy number 10: RBM43, NMI, TNFAIP6, MIR4773-1, MIR4773-2, RN7SL124P.
- chr2:153,761,450–154,453,979, 3 genes, copy number 10 (within-gene range 6–10): DNAJA1P2, GALNT13, PHBP4.
- chr2:154,590,407–156,613,735, 18 genes, copy number 10: RNA5SP107, AC061961.1, KCNJ3, CBX3P6, AC092625.1, RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, LINC01876, HEBP2P1, NR4A2, GPD2.
- chr2:157,210,847–162,838,767, 93 genes, copy number 10 (broad region; genes not listed).
- chr8:39,451,045–39,522,852, 1 gene, copy number 10: ADAM3A.
- chr8:73,670,441–74,208,536, 17 genes, copy number 11 (within-gene range 7–11): AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1.
- chr8:76,162,119–77,537,290, 15 genes, copy number 11: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr8:79,891,553–80,266,155, 10 genes, copy number 11 (within-gene range 7–11): AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3.
- chr8:84,162,118–84,921,844, 7 genes, copy number 10: TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2.
- chr8:88,326,836–89,243,793, 5 genes, copy number 9 (within-gene range 7–9): AC090578.1, RNA5SP272, AC090568.1, AC090578.2, RPSAP74.
- chr8:90,198,389–142,545,009, 703 genes, copy number 9–11 (broad region; genes not listed).
- chr14:99,397,748–106,879,812, 505 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
